Gene-level copy-number profile of specimen HCM-BROD-0012-C71-85A from HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d05815f7-26bd-4f65-ba15-b796e8739b62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0012-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/a1d629f2-7711-4396-b075-a85631029268

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 4,496; copy number 3: 2,728; copy number 4: 48,780; copy number 5: 315; copy number 6: 2,058; copy number 7: 4; copy number 8: 2; copy number 9: 3; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,462,819–64,473,826, 3 genes, copy number 15: CR769776.2, CYP4F25P, CR769776.1.
- chr9:112,957,722–113,050,043, 3 genes, copy number 9 (within-gene range 4–9): ZNF883, MUPP, ZNF883.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
